Somatic mutation profile of tumor specimen TCGA-WL-A834-01A (aliquot TCGA-WL-A834-01A-11D-A351-09) from TCGA case TCGA-WL-A834, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3.
Specimen TCGA-WL-A834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 163e131e-8f3f-482f-8d35-a1d1d93ff1a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WL-A834-10A (Blood Derived Normal), aliquot TCGA-WL-A834-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/711eb847-abd2-4536-a090-fd01051c7453

The open-access MAF lists 105 somatic variants for this specimen: 76 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 27, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPH2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs886039764, COSV54508547; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.727G>C p.E243Q (on ENST00000340800 / NM_022977.2; = p.E202Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV61614089; called by muse, mutect2, varscan2
- ADAMTS2 | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV52373048; called by muse, mutect2, varscan2
- AHNAK | c.12833C>G p.S4278C | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57211476; called by muse, mutect2, varscan2
- ALPK3 | c.4773-1G>A p.X1591_splice | Splice Site (SNP) | VAF 31/41 reads (76%) | catalogued as rs770896454, COSV51932650; called by muse, mutect2, varscan2
- ANKRD16 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs764321371, COSV51947277; called by muse, mutect2, varscan2
- AOPEP | c.1313G>C p.R438P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52917227; called by muse, mutect2, varscan2
- ARHGAP18 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV63764254, COSV63766551; called by muse, mutect2, varscan2
- ARL3 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV53299497; called by muse, mutect2, varscan2
- ATCAY | c.29T>C p.M10T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV56655474; called by muse, mutect2, varscan2
- ATP1A1 | c.1206del p.T403Qfs*55 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as COSV55190590; called by mutect2, pindel, varscan2
- C19orf57 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs765173677, COSV60968044; called by muse, mutect2
- CCSER2 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs1157716005, COSV56504444; called by muse, mutect2, varscan2
- CDC14A | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV60557451; called by muse, mutect2, varscan2
- CDH9 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.703); catalogued as COSV50271737, COSV50529821; called by muse, mutect2, varscan2
- CDK5R1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs963928304, COSV55578476, COSV99912317; called by muse, mutect2, varscan2
- CDKL5 | c.2020T>A p.S674T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as COSV66110980; called by muse, mutect2, varscan2
- CDKL5 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV66110986; called by muse, mutect2, varscan2
- CNTNAP2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs201187461, COSV62216314; called by muse, mutect2, varscan2
- COPG2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV58404268; called by muse, mutect2, varscan2
- CSMD3 | c.10663C>T p.R3555C (on ENST00000297405 / NM_001363185.1; = p.R3386C on NM_052900.3) | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs752615934, COSV52103888; called by muse, mutect2, varscan2
- CST2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.055); catalogued as rs762458988, COSV100491248, COSV59030751; called by muse, mutect2, varscan2
- DSP | c.1990C>G p.Q664E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as CM020673, COSV65792433; called by muse, mutect2, varscan2
- EPHB2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs372282301; called by muse, mutect2
- FBXO32 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV54890848; called by muse, mutect2, varscan2
- FLNB | c.3761A>G p.D1254G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55877554; called by muse, mutect2, varscan2
- FZD8 | c.1263G>T p.W421C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65967787; called by muse, mutect2, varscan2
- GGA2 | c.1364G>C p.W455S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV59168280; called by muse, mutect2, varscan2
- GPR153 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV64938426; called by muse, mutect2
- H1-6 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV58090160; called by muse, mutect2, varscan2
- HRH1 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67955369; called by muse, mutect2, varscan2
- HSD17B7 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV54418104; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs1163661836; called by muse, mutect2, varscan2
- ITIH5 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs560482680, COSV53662315; called by muse, mutect2, varscan2
- KCNMA1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs767099267, COSV54243114; called by muse, mutect2, varscan2
- LCT | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51547786; called by muse, mutect2, varscan2
- LETM2 | c.378C>G p.I126M (on ENST00000379957 / NM_001286819.2; = p.I79M on NM_144652.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV52685998, COSV52688358; called by muse, mutect2, varscan2
- LRP2 | c.7805G>A p.G2602D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs1161371453, COSV55550356; called by muse, mutect2, varscan2
- LRRC37A3 | c.3397G>C p.D1133H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58535039, COSV58536353; called by muse, mutect2, varscan2
- LRRC4B | c.2085C>A p.H695Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.014); catalogued as COSV65349208, COSV65349893; called by muse, mutect2, varscan2
- LRRC4C | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53423560; called by muse, mutect2, varscan2
- MED13 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.353); catalogued as COSV67263154; called by muse, mutect2, varscan2
- MS4A2 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54012344, COSV54014119; called by muse, mutect2, varscan2
- NFATC3 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60473157; called by muse, mutect2, varscan2
- NLRP11 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1307744217, COSV64086882; called by muse, mutect2, varscan2
- NRARP | c.155A>C p.Q52P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV63082818; called by muse, mutect2
- OR4F6 | c.584T>G p.L195W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61026638; called by mutect2, varscan2
- OTUD7A | c.943G>A p.V315I (on ENST00000307050 / NM_001382637.1; = p.V308I on NM_130901.3) | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61038042; called by muse, mutect2, varscan2
- PAIP2B | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV54908741; called by muse, mutect2
- PALM | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1223934139, COSV52767788; called by muse, mutect2, varscan2
- PLEKHH3 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52217386; called by muse, mutect2, varscan2
- POLR2A | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1197117800; called by muse, mutect2, varscan2
- PRKDC | c.6823C>G p.Q2275E | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs765893792, COSV58050054; called by muse, mutect2, varscan2
- PRSS35 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452509235, COSV63800474; called by muse, mutect2, varscan2
- RESF1 | c.5006C>G p.S1669* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV57021508; called by muse, mutect2, varscan2
- ROBO1 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs1428266247, COSV71393672; called by muse, mutect2, varscan2
- ROCK1 | c.2107C>G p.Q703E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764295785, COSV67695678; called by muse, mutect2, varscan2
- RYR2 | c.10328C>A p.A3443D | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV63680709; called by muse, mutect2, varscan2
- RYR3 | c.8494G>C p.E2832Q (on ENST00000389232; = p.E2833Q on NM_001036.6) | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV101214511, COSV66785806; called by muse, mutect2, varscan2
- SIPA1L2 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53389005; called by muse, mutect2, varscan2
- SLC26A3 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758633508, COSV60639959; called by muse, mutect2, varscan2
- SLC2A1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65287227; called by muse, mutect2, varscan2
- SLC34A2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs565847214, COSV65941355; called by muse, mutect2, varscan2
- SLC7A1 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs548607156, COSV66330325; called by muse, mutect2, varscan2
- SNPH | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as rs144751280; called by muse, mutect2, varscan2
- SOX11 | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100431200, COSV58984574; called by muse, mutect2, varscan2
- SPNS3 | c.1273G>C p.G425R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs537260481, COSV61069803; called by muse, mutect2, varscan2
- SSC4D | c.1410C>T p.D470= | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as rs200937354, COSV51882096; called by muse, mutect2, varscan2
- TARS1 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as rs762860954, COSV54308748; called by muse, mutect2, varscan2
- TBXT | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51616506; called by muse, mutect2
- TDRD1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV52589929; called by muse, mutect2, varscan2
- USH2A | c.4583G>A p.C1528Y | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56359725; called by muse, mutect2, varscan2
- YTHDC2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV50737353, COSV50739505; called by muse, mutect2, varscan2
- ZNF133 | c.344G>C p.G115A (on ENST00000316358 / NM_001352454.2; = p.G114A on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60366768; called by muse, mutect2, varscan2
- ZNF16 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs761328705, COSV52762976; called by muse, mutect2
- ECM2 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- ACACB | c.2430G>A p.L810= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100622906; called by muse, mutect2, varscan2
- ANKFY1 | c.1686C>A p.I562= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV58916924; called by muse, varscan2
- CALR3 | c.159G>T p.S53= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV54171258; called by muse, mutect2, varscan2
- CHD6 | c.7248G>A p.L2416= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV64690048; called by muse, mutect2, varscan2
- CNTN6 | c.2367G>C p.L789= | Silent (SNP) | VAF 46/60 reads (77%) | catalogued as COSV63169850; called by muse, mutect2, varscan2
- COL15A1 | c.759C>T p.D253= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs780775882, COSV66643810; called by muse, mutect2, varscan2
- DNAH7 | c.4494C>T p.Y1498= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs556435193, COSV56761278; called by muse, mutect2, varscan2
- GABRA4 | c.888C>T p.V296= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99974084; called by muse, mutect2
- GPR153 | c.921C>G p.L307= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs373529758; called by muse, mutect2, varscan2
- GPR153 | c.60C>G p.L20= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs774155989, COSV64938429, COSV64938613; called by muse, mutect2, varscan2
- ICAM2 | c.703C>T p.L235= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99856911; called by muse, mutect2, varscan2
- INTS7 | c.774G>A p.Q258= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs766911931, COSV65344155; called by muse, mutect2, varscan2
- ISLR2 | c.1470G>A p.A490= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV62302002; called by muse, mutect2, varscan2
- MUSK | c.1872G>A p.Q624= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV51883946; called by muse, mutect2, varscan2
- MYH3 | c.4911G>A p.A1637= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs761510494, COSV56863786; called by muse, mutect2, varscan2
- NUDT7 | c.375G>T p.V125= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV51745141; called by muse, mutect2, varscan2
- OR2T34 | c.639C>A p.L213= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV60900261; called by muse, mutect2, varscan2
- PHF2 | c.270C>T p.I90= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs368398809, COSV63680419; called by muse, mutect2, varscan2
- PTOV1 | c.1161C>T p.V387= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55587524; called by muse, mutect2, varscan2
- PTPRB | c.135G>A p.R45= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV51730299; called by muse, mutect2, varscan2
- RUNX1T1 | c.291C>T p.F97= (on ENST00000265814 / NM_001198628.1; = p.F70= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56144210; called by muse, mutect2, varscan2
- SMARCA4 | c.2547G>A p.R849= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV60792127; called by muse, mutect2, varscan2
- SNAP23 | c.555A>G p.K185= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV99987390; called by muse, mutect2, varscan2
- TXNIP | c.354T>C p.Y118= | Silent (SNP) | VAF 60/93 reads (65%) | catalogued as rs781991546, COSV65220340; called by muse, mutect2, varscan2
- VPS13A | c.6258T>C p.D2086= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100652802; called by muse, mutect2, varscan2
- VPS4B | c.351G>A p.Q117= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV53069120; called by muse, mutect2, varscan2
- ZNF831 | c.1320C>T p.I440= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV64037949; called by muse, mutect2, varscan2
- MAGEC3 | c.1728+58C>T | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as COSV53576014; called by muse, mutect2, varscan2
- POLR2F | c.453-15098C>T | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs372345537; called by muse, mutect2, varscan2
